Somatic mutation profile of tumor specimen C3L-04213-01 (aliquot CPT0277180006) from CPTAC case C3L-04213, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.4 years (13,671 days).
Specimen C3L-04213-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b9eb48a-9ca5-4bf0-866c-b91574185e2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04213-31 (Blood Derived Normal), aliquot CPT0277280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf24d8a0-ffde-45a6-b3c0-55e6ba74ddb4

The open-access MAF lists 102 somatic variants for this specimen: 67 protein-altering or splice-affecting, 23 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 23, RNA 7, Frame Shift Del 4, Splice Site 3, 3'UTR 3, Intron 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 1571/1858 reads (85%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs763323193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL3 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 119/330 reads (36%) | catalogued as rs754085044, COSV54440177; called by muse, mutect2, varscan2
- AKR1C8P | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1224548160; called by muse, mutect2, varscan2
- ANK2 | c.3723A>T p.K1241N | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100001487; called by muse, mutect2, varscan2
- ARHGAP29 | c.513G>A p.S171= | Splice Region (SNP) | VAF 50/133 reads (38%) | catalogued as rs141303887; called by muse, mutect2, varscan2
- AVPR2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 182/467 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs905300222, COSV61685804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- CDH8 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs374778365; called by muse, mutect2, varscan2
- COL4A4 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 140/357 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61629827, COSV61636162; called by muse, mutect2, varscan2
- CROCC2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs1361009112; called by muse, mutect2, varscan2
- CUX1 | c.2986C>T p.R996* | Nonsense Mutation (SNP) | VAF 51/252 reads (20%) | catalogued as COSV52892671; called by muse, mutect2, varscan2
- DOCK3 | c.5000G>A p.R1667Q | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370848128; called by muse, mutect2, varscan2
- EFHC2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs201216295, COSV69553526; called by muse, mutect2, varscan2
- GABRA6 | c.1119G>T p.R373S | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.41); catalogued as COSV99194297, COSV99194594; called by muse, mutect2, varscan2
- GOLGA8M | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs71251168; called by mutect2, varscan2
- GRM3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1365944007, COSV64467506, COSV64477994; called by muse, mutect2, varscan2
- HTR3A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 134/360 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as rs145587443; called by muse, mutect2, varscan2
- IL21R | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV61969700; called by muse, mutect2, varscan2
- KALRN | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99561725, COSV99564534; called by muse, mutect2, varscan2
- KIFC2 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs201279058; called by muse, mutect2, varscan2
- KPNA7 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 179/608 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs1370342038; called by muse, mutect2, varscan2
- MANSC1 | c.466C>A p.H156N | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV67111116; called by muse, mutect2, varscan2
- NPEPPS | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59105369; called by muse, mutect2, varscan2
- OR1J1 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs768778797, COSV52237422; called by muse, mutect2, varscan2
- PCDH15 | c.4540G>A p.D1514N (on ENST00000644397 / NM_001354429.2; = p.K1474= on NM_001142770.3) | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100905342; called by muse, mutect2, varscan2
- PCSK6 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279526800, COSV100083927; called by muse, mutect2, varscan2
- POLA1 | c.4366G>A p.A1456T | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs200953586; called by muse, mutect2, varscan2
- PTEN | c.771del p.F258Sfs*8 | Frame Shift Del (DEL) | VAF 90/154 reads (58%) | catalogued as COSV64295347; called by mutect2, pindel, varscan2
- SACS | c.7505G>A p.R2502Q | Missense Mutation (SNP) | VAF 123/283 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs769239148; called by muse, mutect2, varscan2
- SCN10A | c.599+1G>A p.X200_splice | Splice Site (SNP) | VAF 32/79 reads (41%) | catalogued as rs75991777, CS151607, COSV71862407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMG1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); catalogued as rs1413552646; called by muse, mutect2, varscan2
- STK4 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201208315; called by muse, mutect2, varscan2
- TLE3 | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs538624968; called by muse, mutect2
- TRABD2A | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as rs750677479, COSV100120363; called by muse, mutect2, varscan2
- TSHZ1 | c.878C>T p.S293F (on ENST00000580243 / NM_001308210.2; = p.S248F on NM_005786.6) | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433866; called by muse, mutect2
- YEATS2 | c.3973A>G p.T1325A | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs748724903; called by muse, mutect2, varscan2
- ZNF577 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 161/554 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs369075988; called by muse, mutect2, varscan2
- ARR3 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRWD1 | c.6534del p.R2179Gfs*9 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, varscan2
- BRWD1 | c.6533G>C p.R2178T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by mutect2, varscan2
- CAPS2 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL11A1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DEPDC5 | c.1287+1G>C p.X429_splice | Splice Site (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2638A>C p.T880P | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML5 | c.3685G>C p.G1229R | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2
- FADS3 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GRIA3 | c.216T>A p.N72K | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- INTS6L | c.236del p.N79Ifs*7 | Frame Shift Del (DEL) | VAF 64/192 reads (33%) | called by mutect2, pindel, varscan2
- LRRC7 | c.2503T>G p.S835A (on ENST00000651989 / NM_001370785.2; = p.S802A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEFV | c.2108G>T p.S703I | Missense Mutation (SNP) | VAF 115/299 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- OR2A2 | c.86T>A p.L29H | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- PCDH9 | c.1217_1218del p.E406Gfs*10 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2
- PCMTD2 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PDILT | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PDZK1IP1 | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIM1 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSG5 | c.710-1G>C p.X237_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | called by muse, varscan2
- PTCHD4 | c.829A>C p.I277L | Missense Mutation (SNP) | VAF 153/300 reads (51%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPHKAP | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- THSD4 | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.78451A>T p.I26151F (on ENST00000591111; = p.I18727F on NM_003319.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- USP21 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMYM2 | c.3176A>G p.D1059G | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZMYM3 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF385D | c.236T>C p.I79T | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZXDB | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, varscan2
- APBB1IP | c.804A>G p.K268= | Silent (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2
- BMP6 | c.1440A>G p.P480= | Silent (SNP) | VAF 98/220 reads (45%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4572G>A p.Q1524= | Silent (SNP) | VAF 117/303 reads (39%) | called by muse, mutect2, varscan2
- DNAH10 | c.8571C>T p.R2857= (on ENST00000409039; = p.R2796= on NM_207437.3) | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs984555280, COSV68991099; called by muse, mutect2, varscan2
- ERICH3 | c.2919A>C p.A973= | Silent (SNP) | VAF 68/296 reads (23%) | called by muse, mutect2, varscan2
- EVA1A | c.381C>T p.R127= | Silent (SNP) | VAF 97/279 reads (35%) | catalogued as rs746344001, COSV52060209; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1152A>C p.G384= | Silent (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- GRXCR1 | c.819G>A p.K273= | Silent (SNP) | VAF 65/139 reads (47%) | called by muse, mutect2, varscan2
- IGHV4-31 | c.333G>A p.T111= | Silent (SNP) | VAF 50/390 reads (13%) | catalogued as rs1173731173, rs368159191; called by muse, mutect2
- IL27 | c.576G>A p.P192= | Silent (SNP) | VAF 120/278 reads (43%) | catalogued as rs570953144, COSV60490201; called by muse, varscan2
- MYCL | c.999G>A p.L333= | Silent (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- NGLY1 | c.81C>G p.T27= | Silent (SNP) | VAF 107/377 reads (28%) | called by muse, mutect2, varscan2
- NLRP8 | c.2445C>T p.N815= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as rs111996582, COSV52594890, COSV52595405; called by muse, mutect2, varscan2
- PCDHA7 | c.1233C>T p.S411= | Silent (SNP) | VAF 192/407 reads (47%) | catalogued as COSV100971410; called by muse, mutect2, varscan2
- PCDHGA10 | c.1746G>A p.A582= | Silent (SNP) | VAF 153/437 reads (35%) | called by muse, mutect2, varscan2
- RPRD2 | c.3285T>C p.N1095= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as rs979584472; called by muse, mutect2, varscan2
- SH3GL3 | c.255A>T p.G85= | Silent (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- SMPD3 | c.858C>T p.D286= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs145717053, COSV99545564; called by muse, mutect2, varscan2
- TENT5B | c.468G>A p.P156= | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as rs771303167; called by muse, mutect2, varscan2
- TRAV18 | c.303G>A p.S101= | Silent (SNP) | VAF 49/100 reads (49%) | catalogued as rs553572185; called by muse, mutect2, varscan2
- USP34 | c.417T>C p.S139= | Silent (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- VASN | c.228G>A p.P76= | Silent (SNP) | VAF 135/319 reads (42%) | catalogued as rs781143099, COSV52030052; called by muse, mutect2, varscan2
- ZBTB7A | c.777G>A p.P259= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1410566208; called by muse, mutect2, varscan2
- AC098591.2 | n.743G>A | RNA (SNP) | VAF 212/526 reads (40%) | called by muse, mutect2, varscan2
- APOBR | c.*375C>T | 3'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as rs925688558; called by muse, mutect2, varscan2
- C5orf38 | c.*206C>T | 3'UTR (SNP) | VAF 74/151 reads (49%) | catalogued as COSV57410282; called by muse, mutect2, varscan2
- COL3A1 | c.282+24A>C | Intron (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- EFNB1 | c.*26G>A | 3'UTR (SNP) | VAF 90/220 reads (41%) | catalogued as rs1159525156; called by muse, mutect2, varscan2
- FRMPD2B | n.950G>A | RNA (SNP) | VAF 121/698 reads (17%) | called by muse, mutect2, varscan2
- KRT17P1 | n.284G>A | RNA (SNP) | VAF 46/354 reads (13%) | catalogued as rs766326256; called by muse, mutect2
- LINC00518 | n.810G>T | RNA (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- OR4N3P | n.339A>G | RNA (SNP) | VAF 75/318 reads (24%) | called by muse, mutect2, varscan2
- SKP1P2 | n.298C>A | RNA (SNP) | VAF 76/195 reads (39%) | called by muse, mutect2, varscan2
- SYP | c.227+10C>T | Intron (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- WASH8P | n.1113C>T | RNA (SNP) | VAF 107/476 reads (22%) | catalogued as rs782162873; called by muse, mutect2, varscan2
